Somatic mutation profile of tumor specimen TCGA-FD-A5BV-01A (aliquot TCGA-FD-A5BV-01A-11D-A26M-08) from TCGA case TCGA-FD-A5BV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.9 years (17,501 days).
Specimen TCGA-FD-A5BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a9ca8da-23f4-423d-854e-2598b0b5593a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BV-10A (Blood Derived Normal), aliquot TCGA-FD-A5BV-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0391c980-ddd7-4a2c-a62c-ed8d13a014ef

The open-access MAF lists 133 somatic variants for this specimen: 96 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 35, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, RNA 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.2533dup p.R845Pfs*3 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs767415197; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 22/32 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3497T>C p.I1166T (on ENST00000404938 / NM_001163941.2; = p.I721T on NM_178559.6) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV51704240; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2488A>G p.K830E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV54438659; called by muse, mutect2, varscan2
- ADGRG4 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54950988; called by muse, mutect2, varscan2
- AP1B1 | c.1570T>A p.Y524N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV58015009; called by muse, mutect2, varscan2
- ARHGAP35 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs551334120, COSV68329529; called by muse, mutect2, varscan2
- AVIL | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200603028; called by muse, mutect2, varscan2
- BBS2 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99802067; called by muse, mutect2
- BLVRA | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV55512798; called by muse, mutect2
- C8orf34 | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV57398531; called by muse, mutect2, varscan2
- CAD | c.2482G>T p.E828* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99254389, COSV99254428; called by muse, mutect2, varscan2
- CCL26 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV50013587; called by muse, mutect2, varscan2
- CDK16 | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as COSV52091257; called by muse, mutect2, varscan2
- CEP170B | c.2819G>C p.G940A (on ENST00000453495; = p.G869A on NM_015005.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.299); catalogued as COSV69023543; called by muse, mutect2, varscan2
- CLPSL1 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65814730; called by muse, mutect2, varscan2
- CNOT4 | c.1309C>G p.Q437E (on ENST00000315544 / NM_001190848.1; = p.Q434E on NM_013316.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV59650307; called by muse, mutect2, varscan2
- COL22A1 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs756748110, COSV57326618, COSV57327644; called by muse, mutect2, varscan2
- COL6A1 | c.1065A>C p.Q355H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV62611810; called by muse, mutect2, varscan2
- CPD | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56711135; called by muse, mutect2
- CRB2 | c.3580G>A p.V1194M | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV63502025; called by muse, mutect2, varscan2
- CSMD1 | c.9502A>T p.S3168C (on ENST00000520002; = p.S3167C on NM_033225.6) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59290017; called by muse, mutect2, varscan2
- CSMD3 | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV52117055; called by muse, mutect2, varscan2
- CYP2B6 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57842723, COSV57843227; called by muse, mutect2, varscan2
- CYP4F12 | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV61172654; called by muse, mutect2
- DISP3 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs749520950, COSV53821875; called by muse, mutect2, varscan2
- DNAH5 | c.13339-1G>T p.X4447_splice | Splice Site (SNP) | VAF 26/109 reads (24%) | catalogued as COSV54208409; called by muse, mutect2, varscan2
- DNAH5 | c.7712G>A p.R2571K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54208415; called by muse, mutect2, varscan2
- DNAJC13 | c.1963A>C p.I655L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53446692; called by muse, mutect2, varscan2
- DOCK1 | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs777958830, COSV54732049; called by muse, varscan2
- DSCAM | c.4216G>A p.G1406S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68022104; called by muse, mutect2, varscan2
- E4F1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs774106146, COSV57037891; called by muse, mutect2, varscan2
- EPAS1 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1191268483, COSV55384674; called by muse, mutect2, varscan2
- EPHA6 | c.716A>C p.Y239S | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67561767; called by muse, mutect2, varscan2
- EPHA6 | c.2687G>A p.R896Q (on ENST00000389672 / NM_001080448.3; = p.R288Q on NM_173655.4) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67561777; called by muse, mutect2, varscan2
- EYS | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs756552382, COSV60978209; called by muse, mutect2, varscan2
- FAM171A1 | c.2549C>G p.P850R | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65313915; called by muse, mutect2, varscan2
- FAM47C | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63724304; called by muse, mutect2, varscan2
- GABRA6 | c.1241C>T p.T414I | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.807); catalogued as COSV50878032; called by muse, mutect2, varscan2
- GALNT17 | c.890G>T p.W297L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61150453; called by muse, mutect2, varscan2
- GLI3 | c.4247G>T p.C1416F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs754711120, COSV67885854; called by muse, mutect2, varscan2
- GSK3B | c.1024G>T p.E342* (on ENST00000264235 / NM_001146156.2; = p.E355* on NM_002093.4) | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99954102; called by muse, mutect2, varscan2
- HCN1 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV57496654; called by muse, mutect2, varscan2
- HLA-DQB1 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV66569503; called by muse, mutect2, varscan2
- IFT172 | c.2425G>T p.G809W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53130829; called by muse, mutect2, varscan2
- IQCH | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60049832; called by muse, mutect2, varscan2
- ITGAM | c.480C>G p.S160R | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54934588; called by muse, mutect2, varscan2
- KCNA1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV66836712; called by muse, mutect2, varscan2
- KDM6A | c.4108G>T p.E1370* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as COSV65036914, COSV65038867; called by muse, mutect2, varscan2
- KIAA1210 | c.4274C>G p.P1425R | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV68175846; called by muse, mutect2, varscan2
- KLHL1 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV64767932; called by muse, mutect2, varscan2
- KRTAP5-5 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.907); catalogued as COSV68784440; called by muse, varscan2
- LAMA4 | c.5030G>A p.R1677H (on ENST00000230538 / NM_001105206.3; = p.R1670H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782174781, COSV57892755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK2 | c.3896T>A p.L1299* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100109134; called by muse, mutect2, varscan2
- MAGEC1 | c.2709G>T p.L903F | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV53569081; called by muse, mutect2, varscan2
- MAP3K2 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV61293235; called by muse, mutect2, varscan2
- MED13 | c.3637A>T p.K1213* | Nonsense Mutation (SNP) | VAF 51/97 reads (53%) | catalogued as COSV101180744; called by muse, mutect2, varscan2
- MICU2 | c.1279A>G p.K427E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV101212397; called by muse, mutect2
- MIOS | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV60767285; called by muse, mutect2, varscan2
- MSN | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs765836962, COSV64303460; called by muse, mutect2, varscan2
- MYLK | c.4445T>C p.V1482A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs746820711, COSV60605766; called by muse, mutect2, varscan2
- NCAM2 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53059976; called by muse, mutect2, varscan2
- NID2 | c.1619T>A p.L540H | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53493721; called by muse, mutect2, varscan2
- OR4C15 | c.1053G>T p.M351I (on ENST00000314644; = p.M297I on NM_001001920.2) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); catalogued as COSV100115358; called by muse, mutect2, varscan2
- OR51Q1 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV56179735; called by muse, mutect2
- PDE11A | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1276060984, COSV53688100; called by muse, mutect2, varscan2
- PITPNM2 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54896928; called by muse, mutect2, varscan2
- PLOD3 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV56181558; called by muse, mutect2, varscan2
- PLXNA3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63753370; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1293A>T p.K431N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV62610984; called by muse, mutect2, varscan2
- PPFIA3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs756342224, COSV100494681; called by muse, varscan2
- PSG3 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.678); catalogued as COSV59502851; called by muse, mutect2, varscan2
- PSMC4 | c.817A>C p.K273Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99338109; called by muse, mutect2
- PTPN4 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.941); catalogued as COSV55298358; called by mutect2, varscan2
- RAI14 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867459274, COSV54290391; called by muse, mutect2
- RIPK4 | c.1924G>A p.G642R (on ENST00000352483; = p.G594R on NM_020639.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60186007; called by muse, mutect2, varscan2
- RYR2 | c.12971A>G p.K4324R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as COSV63686412, COSV63713750; called by muse, mutect2
- SCPEP1 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as COSV51853554; called by muse, mutect2, varscan2
- SEC61A2 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as COSV100036741, COSV53650937, COSV53653529; called by muse, mutect2
- SLCO4C1 | c.466T>C p.C156R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60513297; called by muse, mutect2, varscan2
- SOX5 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs758437433, COSV58617375; called by muse, mutect2, varscan2
- SPTA1 | c.6658G>A p.G2220R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63749819; called by muse, mutect2, varscan2
- TIAM2 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs764401822, COSV59690329; called by muse, mutect2, varscan2
- UACA | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as rs1462360350, COSV59853808; called by muse, mutect2, varscan2
- UNC5C | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71658497; called by muse, mutect2, varscan2
- ZDHHC15 | c.176T>G p.I59R | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV64900799; called by muse, mutect2, varscan2
- ZNF432 | c.164A>C p.D55A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV55415543, COSV99659161; called by muse, mutect2, varscan2
- ZNF577 | c.1130T>A p.I377K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56814437; called by muse, mutect2, varscan2
- CDKN2A | c.266dup p.F90Lfs*30 | Frame Shift Ins (INS) | VAF 11/20 reads (55%) | called by mutect2, pindel, varscan2
- CREB3 | c.490_492del p.A164del | In Frame Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- KDM6A | c.3293dup p.L1098Ffs*5 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- PABPN1 | c.411_412del p.E138Afs*26 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- TIMM17A | c.75del p.I26Lfs*19 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- UBE2NL | c.225A>T p.K75N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZFYVE16 | c.153_155delinsA p.R52Nfs*12 | Frame Shift Del (DEL) | VAF 30/42 reads (71%) | called by pindel, varscan2*
- ABCA13 | c.14832A>G p.K4944= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101291179; called by muse, mutect2
- ANAPC2 | c.168G>C p.R56= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV58806523; called by muse, varscan2
- ANK2 | c.1233C>A p.I411= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV52149163; called by muse, mutect2, varscan2
- ATP9A | c.732C>T p.S244= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs557141465, COSV58763943; called by muse, mutect2, varscan2
- C1QTNF1 | c.783C>T p.S261= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs56302593, COSV59260931; called by muse, mutect2, varscan2
- CACNG8 | c.396C>T p.P132= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV54413837; called by muse, mutect2, varscan2
- CDC25C | c.597G>A p.L199= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60398499; called by muse, mutect2, varscan2
- CMYA5 | c.11484C>A p.T3828= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs779285430, COSV71404318; called by muse, mutect2, varscan2
- CPNE4 | c.873C>T p.H291= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1363461993, COSV70190856, COSV70200418; called by muse, mutect2, varscan2
- CYP8B1 | c.1365G>T p.L455= | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as rs772337032, COSV60225726; called by muse, mutect2, varscan2
- DGKB | c.2199G>A p.L733= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV51765712; called by muse, mutect2, varscan2
- FBXO22 | c.987G>A p.R329= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV57616844; called by muse, mutect2, varscan2
- FYCO1 | c.1929G>A p.Q643= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs200743505, COSV56114091; called by muse, mutect2, varscan2
- GDPD2 | c.1410C>T p.N470= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs372467650, COSV65532171; called by muse, mutect2, varscan2
- GNB4 | c.828A>G p.V276= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51708541; called by muse, mutect2, varscan2
- GP5 | c.88C>A p.R30= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV55461988; called by muse, mutect2, varscan2
- GPR20 | c.324G>A p.T108= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs373756599; called by muse, mutect2, varscan2
- ITGAM | c.1185G>A p.V395= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54934599; called by muse, mutect2, varscan2
- KCND3 | c.660G>A p.E220= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV56176368; called by muse, mutect2, varscan2
- MDH1 | c.537G>A p.K179= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV51862547; called by muse, mutect2, varscan2
- MUC16 | c.17325A>G p.E5775= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV67450151; called by muse, mutect2, varscan2
- MYH6 | c.1389C>T p.I463= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs771613733, COSV62448357; called by muse, mutect2, varscan2
- OR2T12 | c.369T>G p.A123= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100527519; called by mutect2, varscan2
- PKHD1 | c.5838C>G p.V1946= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100584574, COSV61863642; called by muse, mutect2, varscan2
- PKHD1L1 | c.5886T>C p.D1962= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV65738697; called by muse, mutect2, varscan2
- PLXNA2 | c.4887C>T p.G1629= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV65438261; called by muse, mutect2, varscan2
- PTX4 | c.1191C>T p.P397= (on ENST00000447419 / NM_001328608.2; = p.P392= on NM_001013658.1) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs148668779, COSV99560265; called by muse, mutect2, varscan2
- RASGEF1C | c.60C>A p.P20= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs374791038, COSV63178073; called by muse, mutect2, varscan2
- SPEN | c.5880C>T p.A1960= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs139575390; called by muse, mutect2, varscan2
- STX5 | c.588G>C p.V196= | Silent (SNP) | VAF 107/432 reads (25%) | catalogued as COSV53678335; called by muse, mutect2, varscan2
- TMEM132B | c.366C>T p.S122= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV54746679, COSV54763125; called by muse, mutect2, varscan2
- TMEM44 | c.1035A>G p.K345= (on ENST00000392432 / NM_001166305.2; = p.K298= on NM_138399.5) | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV56447655; called by muse, mutect2, varscan2
- UROC1 | c.762G>C p.G254= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV52030431, COSV52037323; called by muse, mutect2, varscan2
- XPNPEP2 | c.1956C>T p.A652= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1411509903, COSV64368485; called by muse, mutect2, varscan2
- ZBED4 | c.3372C>T p.C1124= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1367960575, COSV53464106; called by muse, mutect2, varscan2
- DIRC1 | n.443C>A | RNA (SNP) | VAF 21/39 reads (54%) | catalogued as COSV57365820; called by muse, mutect2, varscan2
- FAM74A3 | n.124C>G | RNA (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
